FM case AD16096 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/580a0c55-7347-4231-a9fe-6b71fb262126

Male, 58.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
